Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040030-09A.2 (aliquot TARGET-15-SJMPAL040030-09A.2-01D) from TARGET case TARGET-15-SJMPAL040030, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.5 years (4,931 days).
Specimen TARGET-15-SJMPAL040030-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) babed39f-7ee8-4f7b-adeb-66b42e3e8ac1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040030-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040030-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b23c3a0-71bd-4b6a-b9f9-39c3aa21bed4

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 44/218 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HMCN2 | c.13760C>T p.S4587L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as rs1315283512, COSV56739966; called by muse, mutect2, varscan2
- HYKK | c.300C>A p.H100Q | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV64762241; called by muse, mutect2
- TDRD15 | c.1652C>A p.A551D | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101337961; called by muse, mutect2
- ALDH1A1 | c.1227G>T p.M409I | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.143); called by muse, mutect2
- CNTNAP2 | c.3101A>G p.D1034G | Missense Mutation (SNP) | VAF 105/237 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- JCAD | c.3397G>T p.A1133S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.244); called by muse, mutect2
- LRP1 | c.7315C>T p.R2439W | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RANBP17 | c.387C>A p.F129L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- VWDE | c.236G>T p.C79F | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDIN1 | c.738C>A p.I246= (on ENST00000437989; = p.I148= on NM_032499.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- CREM | c.654C>A p.G218= (on ENST00000429130; = p.G185= on NM_181571.3) | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV59765088; called by muse, mutect2
